Somatic mutation profile of tumor specimen TCGA-S9-A6TU-01A (aliquot TCGA-S9-A6TU-01A-12D-A32B-08) from TCGA case TCGA-S9-A6TU, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.6 years (14,108 days).
Specimen TCGA-S9-A6TU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cd943fa-74da-4b99-9327-058c8bf8a033.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6TU-10A (Blood Derived Normal), aliquot TCGA-S9-A6TU-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a015ac8-976b-48cc-8a24-0f83af241ea3

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 32/42 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AFF4 | c.651T>G p.D217E | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99534512; called by muse, mutect2
- BCL11B | c.2021C>T p.A674V (on ENST00000357195 / NM_001282237.2; = p.A603V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.99); PolyPhen benign (0.043); catalogued as rs746458540, COSV100595083; called by muse, mutect2, varscan2
- CDC42BPB | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs147856179, COSV63476421; called by muse, mutect2, varscan2
- HOXB3 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 166/390 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV100290494, COSV61144820; called by muse, mutect2, varscan2
- MAEL | c.1025A>T p.D342V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1287059788, COSV100901594; called by muse, mutect2
- MOAP1 | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99365609; called by muse, mutect2, varscan2
- PADI3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs146396025; called by muse, mutect2, varscan2
- PARD3 | c.3322A>G p.M1108V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs754788137, COSV100630910; called by muse, mutect2, varscan2
- PDIA4 | c.1792G>A p.V598M (on ENST00000286091 / NM_001371244.1; = p.V597M on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs749787555, COSV99618243; called by muse, mutect2, varscan2
- SCNN1B | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs777426154, COSV100225339; called by muse, mutect2, varscan2
- TTN | c.50260C>T p.Q16754* (on ENST00000591111; = p.Q9330* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV100592163; called by muse, mutect2, varscan2
- UBN2 | c.1126A>T p.S376C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV99943564; called by muse, mutect2, varscan2
- COMMD9 | c.60G>A p.S20= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs777955469, COSV99661190; called by muse, mutect2, varscan2
- GDF6 | c.1107C>T p.D369= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV54625845; called by muse, mutect2, varscan2
- OR11L1 | c.906A>G p.R302= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100869375; called by muse, mutect2, varscan2
- USP25 | c.1545A>G p.R515= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV99583066; called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836513 C>T | 3'Flank (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
